Somatic mutation profile of tumor specimen TCGA-97-7546-01A (aliquot TCGA-97-7546-01A-11D-2036-08) from TCGA case TCGA-97-7546, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 76.4 years (27,913 days).
Specimen TCGA-97-7546-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 565656ba-031b-43a3-a339-a4b444358def.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-97-7546-10A (Blood Derived Normal), aliquot TCGA-97-7546-10A-01D-2036-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ffc4b353-7444-4aa7-9475-91eb3b999227

The open-access MAF lists 301 somatic variants for this specimen: 230 protein-altering or splice-affecting, 61 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 193, Silent 61, Nonsense Mutation 19, Splice Site 7, Frame Shift Del 6, Intron 4, Splice Region 3, RNA 3, Nonstop Mutation 1, 5'Flank 1, 3'Flank 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RAF1 | c.770C>T p.S257L | Missense Mutation (SNP) | VAF 29/94 reads (31%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen benign (0.117); catalogued as rs80338796, CM073301, COSV52574378, COSV52579821; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA3 | c.4661G>T p.W1554L | Missense Mutation (SNP) | VAF 31/130 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as CM074654, COSV57049412; called by muse, mutect2, varscan2
- ABCC12 | c.2371+1G>A p.X791_splice | Splice Site (SNP) | VAF 12/49 reads (24%) | catalogued as COSV60911511; called by muse, mutect2, varscan2
- ABCC5 | c.746G>T p.R249L | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV55586987; called by muse, mutect2, varscan2
- ACP4 | c.812C>G p.S271C | Missense Mutation (SNP) | VAF 29/146 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54516143; called by muse, mutect2, varscan2
- ACSBG1 | c.1063G>T p.A355S | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.564); catalogued as COSV51903308; called by muse, mutect2, varscan2
- ACTC1 | c.602C>A p.S201Y | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.97); catalogued as COSV51757373; called by muse, mutect2, varscan2
- ADAM7 | c.64C>A p.L22I | Missense Mutation (SNP) | VAF 18/180 reads (10%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as COSV51534874; called by muse, mutect2
- ADAMTS6 | c.100G>T p.E34* | Nonsense Mutation (SNP) | VAF 7/22 reads (32%) | catalogued as COSV66856665; called by muse, mutect2, varscan2
- ADGRB3 | c.1325C>T p.A442V | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT tolerated (0.75); PolyPhen possibly damaging (0.516); catalogued as COSV65382193, COSV65395440; called by muse, mutect2
- AFP | c.551G>A p.R184H | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as COSV56923847; called by muse, mutect2, varscan2
- AMDHD2 | c.897G>T p.L299F | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.158); catalogued as COSV53549603; called by muse, mutect2, varscan2
- AMMECR1L | c.407A>G p.Y136C | Missense Mutation (SNP) | VAF 61/201 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.147); catalogued as COSV55759977; called by muse, mutect2, varscan2
- AMY2A | c.56C>A p.P19Q | Missense Mutation (SNP) | VAF 72/277 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as COSV70214260; called by muse, mutect2, varscan2
- APLF | c.1370G>T p.G457V | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV58142419; called by muse, mutect2, varscan2
- ARHGAP11A | c.1891G>T p.E631* | Nonsense Mutation (SNP) | VAF 15/37 reads (41%) | catalogued as COSV64380572; called by muse, mutect2, varscan2
- ARHGDIB | c.514T>C p.Y172H | Missense Mutation (SNP) | VAF 19/131 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56762292; called by muse, mutect2
- ASB9 | c.59C>A p.P20H | Missense Mutation (SNP) | VAF 23/103 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.325); catalogued as COSV66851243; called by muse, mutect2, varscan2
- ASPM | c.3496A>T p.T1166S | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.913); catalogued as COSV54124561; called by muse, mutect2, varscan2
- ASXL3 | c.5386G>T p.V1796F | Missense Mutation (SNP) | VAF 66/169 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.139); catalogued as COSV52456992; called by muse, mutect2, varscan2
- ATF2 | c.208C>T p.P70S | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51367856; called by muse, mutect2
- B3GALNT2 | c.785A>T p.H262L | Missense Mutation (SNP) | VAF 5/104 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV58355870; called by muse, mutect2
- BCOR | c.4288C>T p.Q1430* (on ENST00000378444 / NM_001123385.2; = p.Q1396* on NM_017745.6) | Nonsense Mutation (SNP) | VAF 7/28 reads (25%) | catalogued as rs1309687666, COSV60699481; called by muse, mutect2, varscan2
- BEST3 | c.584C>A p.A195D | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56993813; called by muse, mutect2, varscan2
- BMP3 | c.1255A>G p.I419V | Missense Mutation (SNP) | VAF 35/133 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV51081646; called by muse, mutect2, varscan2
- C11orf71 | c.343+7T>C | Splice Region (SNP) | VAF 8/52 reads (15%) | catalogued as rs768641702, COSV57783910; called by muse, mutect2, varscan2
- CABIN1 | c.3296G>C p.R1099P | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54077014, COSV99572867; called by muse, mutect2, varscan2
- CACNA1F | c.5005C>A p.P1669T | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.021); catalogued as COSV59902964; called by muse, mutect2, varscan2
- CACNA1I | c.692G>T p.W231L | Missense Mutation (SNP) | VAF 43/135 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60800736; called by muse, mutect2, varscan2
- CATSPERD | c.1985G>T p.R662M | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.08); catalogued as COSV100486702; called by muse, mutect2, varscan2
- CATSPERD | c.1986G>T p.R662S | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.194); catalogued as COSV100486704; called by muse, mutect2, varscan2
- CCL7 | c.121A>C p.K41Q | Missense Mutation (SNP) | VAF 31/82 reads (38%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.531); catalogued as COSV52336509, COSV52337205; called by muse, mutect2, varscan2
- CDCA2 | c.551G>T p.G184V | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.018); catalogued as COSV57944260; called by muse, mutect2
- CDH23 | c.1123G>T p.D375Y | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99819563; called by muse, mutect2, varscan2
- CEP192 | c.5747G>T p.R1916L | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as COSV58059740, COSV58070695; called by muse, mutect2, varscan2
- CGA | c.35T>C p.L12P | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV63644078; called by muse, mutect2, varscan2
- CHL1 | c.2360C>A p.A787D (on ENST00000397491 / NM_001253387.1; = p.A803D on NM_006614.4) | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56586269; called by muse, mutect2, varscan2
- CLCA4 | c.172A>T p.T58S | Missense Mutation (SNP) | VAF 45/160 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.145); catalogued as COSV55365974; called by muse, mutect2, varscan2
- COL12A1 | c.5840C>T p.P1947L | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.338); catalogued as rs768626277, COSV59389311, COSV59403904; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL14A1 | c.4759G>A p.G1587R | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV52846977; called by muse, mutect2, varscan2
- COL20A1 | c.3328C>A p.H1110N | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT tolerated (0.5); PolyPhen benign (0.007); catalogued as COSV58911505; called by muse, mutect2, varscan2
- COL5A3 | c.727C>T p.R243C | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.063); catalogued as rs776002651, COSV53406026; called by muse, mutect2, varscan2
- CPA3 | c.145-1G>T p.X49_splice | Splice Site (SNP) | VAF 19/68 reads (28%) | catalogued as COSV56043324; called by muse, mutect2, varscan2
- CSMD3 | c.6238C>A p.Q2080K (on ENST00000297405 / NM_001363185.1; = p.Q1976K on NM_052900.3) | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.841); catalogued as COSV52133376; called by muse, mutect2, varscan2
- CT45A10 | c.408C>A p.C136* | Nonsense Mutation (SNP) | VAF 43/140 reads (31%) | catalogued as COSV65921088; called by muse, mutect2, varscan2
- CTDSP2 | c.622A>T p.R208W | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66079721; called by muse, mutect2, varscan2
- CUL4A | c.1172A>G p.K391R (on ENST00000375440 / NM_001008895.4; = p.K291R on NM_003589.3) | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.052); catalogued as COSV58371130; called by muse, mutect2, varscan2
- CYP26B1 | c.1049G>A p.G350E | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0.012); catalogued as COSV50010705; called by muse, mutect2, varscan2
- CYSLTR1 | c.186G>T p.M62I | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.621); catalogued as COSV64819382; called by muse, mutect2, varscan2
- DAAM1 | c.575C>G p.S192C | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62834108; called by muse, mutect2, varscan2
- DGKB | c.1377C>A p.F459L | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.734); catalogued as rs1336285309, COSV51761600, COSV51820712; called by muse, mutect2, varscan2
- DGKK | c.3806C>A p.S1269Y | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.055); catalogued as COSV65706319; called by muse, mutect2, varscan2
- DMD | c.5318C>A p.T1773N | Missense Mutation (SNP) | VAF 35/138 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.454); catalogued as rs956323929, COSV63734371; called by muse, mutect2, varscan2
- DMD | c.3335G>T p.G1112V | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV63734383; called by muse, mutect2, varscan2
- DNAH17 | c.2350A>T p.K784* | Nonsense Mutation (SNP) | VAF 24/106 reads (23%) | catalogued as COSV67749515; called by muse, mutect2
- DNAH8 | c.10163G>T p.C3388F | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.361); catalogued as COSV59424183; called by muse, mutect2, varscan2
- DOCK11 | c.113A>G p.K38R | Missense Mutation (SNP) | VAF 41/129 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0.03); catalogued as COSV52233495; called by muse, mutect2, varscan2
- EBF1 | c.339G>T p.Q113H | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.043); catalogued as COSV100565427; called by muse, mutect2, varscan2
- EOLA2 | c.167T>C p.L56P | Missense Mutation (SNP) | VAF 33/168 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); catalogued as COSV62206931; called by muse, mutect2, varscan2
- EPHA3 | c.1440A>T p.Q480H | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV100349933, COSV60693734, COSV60694993; called by muse, mutect2, varscan2
- EPHA6 | c.2617C>T p.L873F (on ENST00000389672 / NM_001080448.3; = p.L265F on NM_173655.4) | Missense Mutation (SNP) | VAF 46/135 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67558454; called by muse, mutect2, varscan2
- EPHA7 | c.2009G>T p.G670V | Missense Mutation (SNP) | VAF 37/114 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65177164; called by muse, mutect2, varscan2
- EVC2 | c.1011G>T p.W337C | Missense Mutation (SNP) | VAF 27/99 reads (27%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.574); catalogued as COSV60387744; called by muse, mutect2, varscan2
- FAT4 | c.4268G>C p.G1423A | Missense Mutation (SNP) | VAF 9/105 reads (9%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.814); catalogued as COSV67881205; called by muse, mutect2
- FLG2 | c.2492C>A p.S831Y | Missense Mutation (SNP) | VAF 138/484 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs867314560, COSV66166576; called by muse, varscan2
- FLNA | c.2510A>G p.K837R | Missense Mutation (SNP) | VAF 37/161 reads (23%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.809); catalogued as COSV61037250; called by muse, mutect2, varscan2
- FRMPD1 | c.1674G>T p.Q558H | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT tolerated (0.17); PolyPhen benign (0.135); catalogued as COSV66699115; called by muse, mutect2, varscan2
- FTCD | c.515G>T p.G172V | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99384769; called by muse, mutect2, varscan2
- GALNT14 | c.1213G>T p.E405* | Nonsense Mutation (SNP) | VAF 9/40 reads (23%) | catalogued as COSV61102355, COSV61103649; called by muse, mutect2, varscan2
- GJA10 | c.829C>A p.P277T | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.218); catalogued as COSV101005301; called by muse, mutect2, varscan2
- GJA10 | c.830C>A p.P277H | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.04); catalogued as COSV101005304; called by muse, mutect2, varscan2
- GK | c.1264G>A p.G422R (on ENST00000427190 / NM_001205019.2; = p.G416R on NM_000167.6) | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.312); catalogued as COSV66732060; called by muse, mutect2, varscan2
- GLOD5 | c.250G>A p.E84K | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as rs1557017311, COSV57488756, COSV57490344; called by muse, mutect2, varscan2
- GPR107 | c.1022G>A p.G341E | Missense Mutation (SNP) | VAF 30/103 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61277128; called by muse, mutect2, varscan2
- GRM1 | c.3421G>A p.D1141N | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.031); catalogued as COSV51108598; called by muse, mutect2
- GRM8 | c.9C>A p.C3* | Nonsense Mutation (SNP) | VAF 16/62 reads (26%) | catalogued as COSV58800898, COSV58815342; called by muse, mutect2, varscan2
- GSTA4 | c.252G>T p.K84N | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.043); catalogued as COSV63955124; called by muse, mutect2, varscan2
- GUCY1A2 | c.458G>A p.G153E | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.97); PolyPhen probably damaging (1); catalogued as COSV56477375; called by muse, varscan2
- GUCY1A2 | c.380A>T p.E127V | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV56477395; called by muse, varscan2
- HELQ | c.3078G>T p.Q1026H | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV55024111; called by muse, mutect2, varscan2
- HERC1 | c.4792T>G p.F1598V | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.081); catalogued as COSV71245904; called by muse, varscan2
- HHIPL2 | c.1763A>C p.Y588S | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.29); PolyPhen benign (0.011); catalogued as COSV58563137; called by muse, varscan2
- HID1 | c.1040G>T p.R347L | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.107); catalogued as COSV100585963, COSV100586117; called by muse, mutect2, varscan2
- HRH3 | c.574T>A p.F192I | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV58047438; called by muse, mutect2, varscan2
- IGSF1 | c.1106C>A p.T369N | Missense Mutation (SNP) | VAF 40/93 reads (43%) | SIFT tolerated (0.47); PolyPhen benign (0.133); catalogued as COSV100812078, COSV63836033; called by muse, mutect2, varscan2
- IL9R | c.370C>G p.H124D | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.009); catalogued as COSV54898149; called by muse, mutect2, varscan2
- INHBA | c.926G>T p.R309L | Missense Mutation (SNP) | VAF 32/149 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.317); catalogued as COSV54219500, COSV54222254; called by muse, mutect2, varscan2
- ITGA2 | c.1421G>T p.G474V | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.807); catalogued as rs1265561130, COSV56856207; called by muse, mutect2, varscan2
- ITIH5 | c.2213G>T p.R738L | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53659623, COSV53675680; called by muse, mutect2, varscan2
- ITPRIPL2 | c.1189C>T p.Q397* | Nonsense Mutation (SNP) | VAF 61/296 reads (21%) | catalogued as COSV67347300; called by muse, mutect2, varscan2
- KANK4 | c.2983C>A p.L995M | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.003); catalogued as COSV58091939; called by muse, mutect2
- KCNA6 | c.495G>T p.E165D | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV54973963; called by muse, mutect2, varscan2
- KIF1A | c.3281G>T p.S1094I | Missense Mutation (SNP) | VAF 32/128 reads (25%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.983); catalogued as COSV57482485, COSV57500553; called by muse, mutect2, varscan2
- KLHL4 | c.1125A>C p.L375F | Missense Mutation (SNP) | VAF 31/113 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV64138975; called by muse, mutect2, varscan2
- KRT28 | c.1303C>T p.R435C | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.009); catalogued as rs756589216, COSV60683565; called by muse, mutect2, varscan2
- KRTAP20-2 | c.20A>G p.Y7C | Missense Mutation (SNP) | VAF 40/107 reads (37%) | PolyPhen benign (0.046); catalogued as rs780688726, COSV58182503; called by muse, mutect2, varscan2
- L1CAM | c.469C>A p.P157T | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.543); catalogued as COSV62826745; called by muse, mutect2, varscan2
- LAMB2 | c.1855A>G p.M619V | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs367670275; called by muse, mutect2, varscan2
- LILRA4 | c.520G>T p.G174* | Nonsense Mutation (SNP) | VAF 3/46 reads (7%) | catalogued as COSV99392970; called by muse, mutect2
- LIN9 | c.1234G>C p.E412Q (on ENST00000366808 / NM_001270410.2; = p.E357Q on NM_173083.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.109); catalogued as COSV60243793; called by muse, mutect2, varscan2
- LMLN | c.188C>T p.P63L | Missense Mutation (SNP) | VAF 39/93 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.123); catalogued as rs781075916, COSV54560167; called by muse, mutect2, varscan2
- LMX1A | c.718C>T p.Q240* | Nonsense Mutation (SNP) | VAF 11/45 reads (24%) | catalogued as COSV54216510; called by muse, mutect2, varscan2
- LRBA | c.5585G>T p.W1862L | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV63949719; called by muse, mutect2, varscan2
- LRFN5 | c.361G>A p.G121S | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53242705; called by muse, mutect2, varscan2
- LRRC4C | c.1294G>T p.V432F | Missense Mutation (SNP) | VAF 35/152 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.219); catalogued as rs368163511, COSV53417851; called by muse, mutect2, varscan2
- LRRC4C | c.965C>A p.S322* | Nonsense Mutation (SNP) | VAF 16/64 reads (25%) | catalogued as COSV53417859; called by muse, mutect2, varscan2
- LRRC56 | c.102G>T p.Q34H | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.626); catalogued as COSV99529706; called by muse, mutect2, varscan2
- LRRTM4 | c.1029G>T p.K343N | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.981); catalogued as COSV69138961; called by muse, mutect2, varscan2
- LSM14A | c.1330G>C p.G444R | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.303); catalogued as COSV70884659; called by muse, mutect2, varscan2
- MAP3K10 | c.1262G>T p.R421L | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.246); catalogued as COSV53420371, COSV99454725; called by muse, mutect2
- MDM2 | c.1261G>C p.E421Q | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.544); catalogued as COSV50697861; called by muse, mutect2, varscan2
- MEGF10 | c.3379G>T p.D1127Y | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV57244864; called by muse, mutect2, varscan2
- MGAM | c.1000G>T p.A334S | Missense Mutation (SNP) | VAF 26/119 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.073); catalogued as COSV72073573; called by muse, mutect2, varscan2
- MRPL24 | c.189G>T p.E63D | Missense Mutation (SNP) | VAF 38/206 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.279); catalogued as rs1278831396, COSV61975524; called by muse, mutect2, varscan2
- MTMR1 | c.985G>C p.D329H | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV64892199; called by muse, mutect2, varscan2
- MUC16 | c.33748G>T p.V11250F | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.35); catalogued as rs746867838, COSV67444078; called by muse, mutect2, varscan2
- MUC16 | c.27917G>T p.S9306I | Missense Mutation (SNP) | VAF 12/164 reads (7%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.006); catalogued as rs1417001381, COSV67444084; called by muse, mutect2
- MYH11 | c.5755C>G p.R1919G | Missense Mutation (SNP) | VAF 103/209 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs750085824, COSV55542652, COSV55563383; called by muse, mutect2, varscan2
- NAF1 | c.819G>A p.M273I | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.112); catalogued as rs768892882, COSV56803205; called by muse, mutect2, varscan2
- NCALD | c.233G>A p.G78E | Missense Mutation (SNP) | VAF 19/160 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV55271002; called by muse, mutect2, varscan2
- NDST3 | c.2399+1G>T p.X800_splice | Splice Site (SNP) | VAF 14/62 reads (23%) | catalogued as rs1481295620, COSV56612925; called by muse, mutect2, varscan2
- NES | c.3433G>C p.E1145Q | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV63960346; called by muse, mutect2, varscan2
- NLRP9 | c.23A>T p.D8V | Missense Mutation (SNP) | VAF 21/107 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV60459261, COSV60459405; called by muse, mutect2, varscan2
- NOTCH1 | c.2014G>T p.G672W | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53027530, COSV99490187, COSV99493594; called by muse, mutect2, varscan2
- NOTCH2 | c.1460A>T p.K487I | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.731); catalogued as COSV56681337; called by muse, mutect2, varscan2
- NR1H4 | c.458C>T p.T153I (on ENST00000551379 / NM_001206993.2; = p.T143I on NM_005123.4) | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1566445307, COSV51857884; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NR5A1 | c.268G>A p.G90S | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as CM126111, COSV65294585; called by muse, mutect2, varscan2
- NRXN2 | c.1577C>A p.P526H | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55446957; called by muse, mutect2, varscan2
- NSDHL | c.231G>T p.Q77H | Missense Mutation (SNP) | VAF 62/258 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV64743143; called by muse, mutect2, varscan2
- NSMAF | c.1888A>G p.K630E | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.497); catalogued as COSV50683709; called by muse, mutect2, varscan2
- NUP133 | c.2393G>T p.R798L | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); catalogued as COSV54568158, COSV99772635; called by muse, mutect2, varscan2
- NUP188 | c.740G>T p.R247M | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV101001241; called by muse, mutect2, varscan2
- NUP188 | c.741G>T p.R247S | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV65360201; called by muse, mutect2, varscan2
- OBSCN | c.14640G>T p.Q4880H | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1257090274, COSV52738942, COSV52783814; called by muse, mutect2, varscan2
- OLIG3 | c.158G>A p.G53E | Missense Mutation (SNP) | VAF 19/144 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs1252074622, COSV100880235, COSV62988342; called by muse, mutect2, varscan2
- OLIG3 | c.157G>A p.G53R | Missense Mutation (SNP) | VAF 20/147 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.091); catalogued as rs1254847652, COSV100880238, COSV100880358; called by muse, mutect2, varscan2
- OR10C1 | c.703C>T p.R235C (on ENST00000622521; = p.R233C on NM_013941.3) | Missense Mutation (SNP) | VAF 43/271 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.143); catalogued as rs147036236, COSV65822212; called by muse, mutect2, varscan2
- OR13F1 | c.774G>T p.M258I | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.034); catalogued as COSV58250677; called by muse, mutect2, varscan2
- OR4C16 | c.557C>G p.A186G | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.656); catalogued as COSV58940588; called by muse, mutect2, varscan2
- OR4E2 | c.584C>A p.T195K | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV57731768; called by muse, mutect2, varscan2
- OTOF | c.4087G>T p.E1363* (on ENST00000272371 / NM_194248.3; = p.E596* on NM_004802.4) | Nonsense Mutation (SNP) | VAF 8/69 reads (12%) | catalogued as COSV55495312, COSV55513980; called by muse, mutect2, varscan2
- P2RX2 | c.305C>A p.P102H (on ENST00000343948 / NM_170683.4; = p.P79= on NM_012226.5) | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57674011; called by muse, mutect2
- P2RY10 | c.365G>A p.C122Y | Missense Mutation (SNP) | VAF 49/175 reads (28%) | SIFT tolerated (0.92); PolyPhen benign (0.003); catalogued as COSV50680333; called by muse, mutect2, varscan2
- PCDH11X | c.3535C>T p.Q1179* | Nonsense Mutation (SNP) | VAF 39/176 reads (22%) | catalogued as COSV53441935; called by muse, mutect2, varscan2
- PCDHA1 | c.1991C>T p.T664I | Missense Mutation (SNP) | VAF 27/112 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as rs1554118212, COSV65372624; called by muse, mutect2, varscan2
- PCDHA6 | c.2380G>C p.D794H | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.005); catalogued as COSV65341771; called by muse, mutect2, varscan2
- PCDHGB7 | c.626A>T p.H209L | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as COSV53897437; called by muse, mutect2, varscan2
- PCYT1B | c.395G>C p.R132T | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63263907, COSV63264522, COSV63267067; called by muse, mutect2, varscan2
- PDE10A | c.1727A>G p.Q576R | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.98); catalogued as COSV63090905; called by muse, mutect2, varscan2
- PDGFRA | c.1557C>A p.P519= | Splice Region (SNP) | VAF 14/63 reads (22%) | catalogued as COSV99955902; called by muse, mutect2, varscan2
- PDGFRA | c.1558A>G p.T520A | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV99955907; called by muse, mutect2, varscan2
- PEG3 | c.3408C>G p.D1136E | Missense Mutation (SNP) | VAF 57/181 reads (31%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.994); catalogued as COSV55624431; called by muse, mutect2, varscan2
- PELP1 | c.166G>T p.V56L | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.107); catalogued as COSV99342633; called by muse, mutect2, varscan2
- PHEX | c.1283A>G p.Q428R | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.022); catalogued as COSV65073691; called by muse, mutect2, varscan2
- PLXNC1 | c.3061T>C p.F1021L | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51569258; called by muse, mutect2, varscan2
- PPP1R16B | c.1354G>C p.D452H | Missense Mutation (SNP) | VAF 53/215 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.679); catalogued as COSV55374076; called by muse, mutect2, varscan2
- PRICKLE1 | c.2480A>G p.N827S | Missense Mutation (SNP) | VAF 45/112 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV58203862; called by muse, mutect2, varscan2
- PRKX | c.876C>T p.N292= | Splice Region (SNP) | VAF 7/29 reads (24%) | catalogued as rs1301840503, COSV53322064; called by muse, mutect2, varscan2
- PRRC2C | c.3788G>T p.R1263L (on ENST00000367742; = p.R1261L on NM_015172.4) | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.645); catalogued as COSV58900806; called by muse, mutect2, varscan2
- PTPRD | c.900C>A p.Y300* | Nonsense Mutation (SNP) | VAF 11/62 reads (18%) | catalogued as COSV61927918; called by muse, mutect2, varscan2
- PTPRT | c.2343G>T p.L781F | Missense Mutation (SNP) | VAF 68/202 reads (34%) | SIFT tolerated (0.71); PolyPhen possibly damaging (0.879); catalogued as COSV61959633, COSV62005816; called by muse, mutect2, varscan2
- PXDNL | c.3316G>T p.G1106C | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV62477633; called by muse, mutect2
- QDPR | c.546-1G>T p.X182_splice | Splice Site (SNP) | VAF 3/31 reads (10%) | catalogued as COSV99845708; called by muse, mutect2
- RADX | c.301G>C p.D101H | Missense Mutation (SNP) | VAF 51/173 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65317794; called by muse, mutect2, varscan2
- RAPGEF1 | c.2071G>T p.D691Y | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64697547; called by muse, mutect2, varscan2
- RERGL | c.319A>T p.T107S | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT tolerated (0.71); PolyPhen benign (0.038); catalogued as COSV57460817; called by muse, mutect2, varscan2
- RGS21 | c.457T>G p.*153Gext*3 | Nonstop Mutation (SNP) | VAF 10/24 reads (42%) | catalogued as COSV69881501; called by muse, varscan2
- RNF182 | c.110T>G p.L37R | Missense Mutation (SNP) | VAF 38/145 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV101337853; called by muse, mutect2, varscan2
- RNF213 | c.8834G>A p.R2945H | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.077); catalogued as rs76918558, COSV60389944; called by muse, mutect2, varscan2
- RYR2 | c.11806G>T p.A3936S | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV63660801; called by muse, mutect2, varscan2
- SATB2 | c.1853G>T p.R618L | Missense Mutation (SNP) | VAF 30/119 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV53477887, COSV53484287; called by muse, mutect2, varscan2
- SCN8A | c.2926C>T p.L976F | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61976412; called by muse, mutect2
- SDK1 | c.5230G>T p.A1744S | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT tolerated (0.37); PolyPhen benign (0.018); catalogued as COSV67356203; called by muse, mutect2, varscan2
- SEMA4C | c.1988G>T p.G663V | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as COSV100560791; called by muse, mutect2, varscan2
- SEMA4C | c.1987G>T p.G663W | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100560793; called by muse, mutect2, varscan2
- SF3A1 | c.1018G>T p.E340* | Nonsense Mutation (SNP) | VAF 49/189 reads (26%) | catalogued as COSV53167163; called by muse, mutect2, varscan2
- SH3GL2 | c.670G>T p.E224* | Nonsense Mutation (SNP) | VAF 18/116 reads (16%) | catalogued as COSV101014108; called by muse, mutect2, varscan2
- SHC2 | c.1498A>G p.M500V | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.029); catalogued as rs369081529; called by muse, mutect2
- SLC28A1 | c.1784G>A p.G595E | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT tolerated (0.24); PolyPhen benign (0.033); catalogued as rs768052785, COSV54476348, COSV54481299; called by muse, mutect2, varscan2
- SLC9A7 | c.794-2A>C p.X265_splice | Splice Site (SNP) | VAF 10/30 reads (33%) | catalogued as COSV60377471; called by muse, mutect2, varscan2
- SLC9A7 | c.247C>G p.L83V | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.206); catalogued as COSV60377477; called by muse, mutect2, varscan2
- SLITRK2 | c.815G>T p.S272I | Missense Mutation (SNP) | VAF 52/162 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV59423005; called by muse, mutect2, varscan2
- SNX24 | c.218A>T p.Q73L | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as COSV54446636; called by muse, mutect2, varscan2
- SOBP | c.1433C>A p.P478Q | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57995626; called by muse, mutect2, varscan2
- SORCS1 | c.248G>A p.G83E | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.228); catalogued as COSV53840799; called by muse, mutect2, varscan2
- SPTA1 | c.4825C>G p.Q1609E | Missense Mutation (SNP) | VAF 42/125 reads (34%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.952); catalogued as COSV63748738; called by muse, mutect2, varscan2
- SST | c.284C>A p.A95D | Missense Mutation (SNP) | VAF 27/236 reads (11%) | SIFT tolerated (0.62); PolyPhen benign (0.367); catalogued as COSV99809790; called by muse, mutect2, varscan2
- SST | c.283G>C p.A95P | Missense Mutation (SNP) | VAF 26/236 reads (11%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as COSV99809791; called by muse, mutect2, varscan2
- ST6GALNAC3 | c.833G>T p.R278M | Missense Mutation (SNP) | VAF 13/53 reads (25%) | PolyPhen probably damaging (1); catalogued as COSV60320356, COSV60350424; called by muse, mutect2, varscan2
- STON2 | c.2570A>T p.D857V (on ENST00000649389 / NM_001366849.2; = p.D800V on NM_001256430.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 50/143 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50842280; called by muse, mutect2, varscan2
- TAGAP | c.1084G>T p.V362L | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated (0.86); PolyPhen benign (0.003); catalogued as COSV57850466; called by muse, mutect2, varscan2
- TAS2R1 | c.437A>T p.K146I | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.852); catalogued as COSV66778082; called by muse, mutect2, varscan2
- TBC1D25 | c.1417C>A p.P473T | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.17); catalogued as COSV65123206; called by muse, mutect2, varscan2
- TBC1D32 | c.633G>T p.W211C | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV51536096; called by muse, mutect2, varscan2
- TFEC | c.29C>A p.P10Q | Missense Mutation (SNP) | VAF 32/118 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55397464; called by muse, mutect2, varscan2
- THRA | c.441G>T p.K147N | Missense Mutation (SNP) | VAF 84/183 reads (46%) | SIFT deleterious (0.05); PolyPhen benign (0.368); catalogued as COSV52840662; called by muse, mutect2, varscan2
- THRAP3 | c.652G>C p.E218Q | Missense Mutation (SNP) | VAF 31/107 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.038); catalogued as COSV63566591; called by muse, mutect2, varscan2
- TLR1 | c.112C>A p.H38N | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT tolerated (0.3); PolyPhen benign (0.005); catalogued as COSV58303115; called by muse, mutect2, varscan2
- TMEM132B | c.928G>A p.D310N | Missense Mutation (SNP) | VAF 18/170 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV54744393; called by muse, mutect2, varscan2
- TP53RK | c.284G>A p.G95E | Missense Mutation (SNP) | VAF 64/259 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64508788; called by muse, mutect2, varscan2
- TRIM49 | c.1283G>C p.S428T | Missense Mutation (SNP) | VAF 20/156 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.862); catalogued as COSV100315943; called by muse, varscan2
- TRIML1 | c.112G>T p.V38L | Missense Mutation (SNP) | VAF 60/240 reads (25%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV60193272; called by muse, mutect2, varscan2
- TRIML2 | c.222G>T p.R74S | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.373); catalogued as COSV58714526; called by muse, mutect2, varscan2
- TSPOAP1 | c.1835C>T p.S612F | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); catalogued as COSV52103884; called by muse, mutect2, varscan2
- TTI1 | c.1131C>A p.S377R | Missense Mutation (SNP) | VAF 62/204 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.054); catalogued as COSV65060396; called by muse, mutect2, varscan2
- UBASH3B | c.602-2A>T p.X201_splice | Splice Site (SNP) | VAF 53/311 reads (17%) | catalogued as COSV52489997; called by muse, mutect2, varscan2
- USH2A | c.3116C>A p.A1039E | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1306207778, COSV56326600, COSV56357589; called by muse, mutect2, varscan2
- UTP14A | c.1749+2T>A p.X583_splice | Splice Site (SNP) | VAF 35/145 reads (24%) | catalogued as COSV64086245; called by muse, mutect2, varscan2
- VAMP7 | c.655A>T p.K219* | Nonsense Mutation (SNP) | VAF 4/40 reads (10%) | catalogued as COSV99387778; called by muse, mutect2
- VPS13D | c.2123C>A p.T708N | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT tolerated (0.33); PolyPhen benign (0.015); catalogued as COSV50621561; called by muse, mutect2, varscan2
- WDFY3 | c.2485G>T p.D829Y | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.759); catalogued as COSV55693206; called by muse, mutect2, varscan2
- ZBTB41 | c.1906T>C p.C636R | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66358638; called by muse, mutect2, varscan2
- ZFP42 | c.169G>T p.E57* | Nonsense Mutation (SNP) | VAF 18/89 reads (20%) | catalogued as COSV58816355; called by muse, mutect2, varscan2
- ZNF251 | c.1671G>T p.W557C | Missense Mutation (SNP) | VAF 33/79 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.237); catalogued as COSV52955843; called by muse, mutect2, varscan2
- ZNF304 | c.736G>C p.A246P | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV56583226; called by muse, mutect2, varscan2
- ZNF350 | c.56G>A p.W19* | Nonsense Mutation (SNP) | VAF 34/134 reads (25%) | catalogued as COSV54707578; called by muse, mutect2, varscan2
- ZNF408 | c.1732C>T p.P578S | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV61237551, COSV61238944; called by muse, mutect2, varscan2
- ZNF578 | c.284G>T p.S95I | Missense Mutation (SNP) | VAF 30/143 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.566); catalogued as COSV69735916; called by muse, mutect2, varscan2
- ZNF714 | c.1285G>C p.E429Q | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.432); catalogued as COSV52509681, COSV99395324; called by muse, mutect2, varscan2
- ZNF799 | c.1817A>T p.H606L | Missense Mutation (SNP) | VAF 20/124 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV70121863; called by muse, varscan2
- ZSCAN1 | c.839C>T p.S280L | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as rs745742690, COSV56601609; called by muse, mutect2, varscan2
- APOBEC3D | c.463del p.A155Pfs*3 | Frame Shift Del (DEL) | VAF 10/65 reads (15%) | called by mutect2, pindel, varscan2
- APOBR | c.2171A>G p.D724G (on ENST00000431282; = p.D733G on NM_018690.4) | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.439); called by muse, mutect2
- CDX4 | c.180del p.S61Afs*38 | Frame Shift Del (DEL) | VAF 17/58 reads (29%) | called by mutect2, pindel, varscan2
- DSCAM | c.2243dup p.N748Kfs*38 | Frame Shift Ins (INS) | VAF 18/71 reads (25%) | called by mutect2, pindel, varscan2
- IL4 | c.347del p.G116Afs*5 | Frame Shift Del (DEL) | VAF 6/52 reads (12%) | called by mutect2, pindel
- KIR3DL3 | c.247G>T p.G83C | Missense Mutation (SNP) | VAF 36/207 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- NCR1 | c.433del p.R145Vfs*2 | Frame Shift Del (DEL) | VAF 8/52 reads (15%) | called by mutect2, pindel, varscan2
- NOL4 | c.112del p.Q38Sfs*54 | Frame Shift Del (DEL) | VAF 22/128 reads (17%) | called by mutect2, pindel, varscan2
- OVCH1 | c.1223del p.T408Mfs*19 | Frame Shift Del (DEL) | VAF 16/120 reads (13%) | called by mutect2, pindel, varscan2
- ACVR1C | c.1407A>T p.G469= | Silent (SNP) | VAF 20/73 reads (27%) | catalogued as COSV54643674; called by muse, mutect2, varscan2
- ADAMDEC1 | c.24A>T p.L8= | Silent (SNP) | VAF 5/16 reads (31%) | catalogued as COSV56474028; called by muse, mutect2
- ADCY2 | c.2313G>T p.V771= | Silent (SNP) | VAF 42/125 reads (34%) | catalogued as COSV57858581, COSV57880126; called by muse, mutect2, varscan2
- AXL | c.456C>T p.A152= | Silent (SNP) | VAF 5/36 reads (14%) | catalogued as COSV56563638; called by muse, mutect2, varscan2
- BTRC | c.147A>T p.T49= | Silent (SNP) | VAF 18/54 reads (33%) | catalogued as COSV64560377; called by muse, mutect2, varscan2
- C1orf94 | c.876G>T p.L292= (on ENST00000488417 / NM_001134734.2; = p.L102= on NM_032884.5) | Silent (SNP) | VAF 19/64 reads (30%) | catalogued as COSV64912928; called by muse, mutect2, varscan2
- CABIN1 | c.3297G>T p.R1099= | Silent (SNP) | VAF 10/50 reads (20%) | catalogued as COSV99572868; called by muse, mutect2, varscan2
- CAV1 | c.219A>G p.A73= | Silent (SNP) | VAF 8/30 reads (27%) | catalogued as COSV61952534; called by muse, mutect2, varscan2
- CENPF | c.8358G>A p.K2786= | Silent (SNP) | VAF 6/37 reads (16%) | catalogued as COSV65272631; called by muse, mutect2, varscan2
- CETN2 | c.46C>A p.R16= | Silent (SNP) | VAF 25/97 reads (26%) | catalogued as rs782168993, COSV64743137, COSV64743839; called by muse, mutect2, varscan2
- CFAP221 | c.1506G>T p.S502= | Silent (SNP) | VAF 5/21 reads (24%) | catalogued as COSV54653891; called by muse, mutect2, varscan2
- CFAP47 | c.1041C>A p.T347= | Silent (SNP) | VAF 10/66 reads (15%) | catalogued as COSV52880518; called by muse, mutect2, varscan2
- CPA3 | c.1092C>T p.D364= | Silent (SNP) | VAF 8/80 reads (10%) | catalogued as rs1378305016, COSV56043335, COSV99936080; called by muse, mutect2
- CRMP1 | c.1206C>A p.A402= | Silent (SNP) | VAF 32/126 reads (25%) | catalogued as COSV100272275, COSV61478148; called by muse, mutect2, varscan2
- CROCC | c.5403G>T p.L1801= | Silent (SNP) | VAF 15/63 reads (24%) | catalogued as COSV65003580; called by muse, mutect2, varscan2
- DIRAS3 | c.654C>T p.T218= | Silent (SNP) | VAF 52/149 reads (35%) | catalogued as COSV63970438; called by muse, mutect2, varscan2
- DNAH17 | c.2352G>A p.K784= | Silent (SNP) | VAF 24/103 reads (23%) | catalogued as COSV67749510; called by muse, mutect2
- DNAH2 | c.10326C>T p.N3442= | Silent (SNP) | VAF 16/132 reads (12%) | catalogued as rs758800240, COSV66716203; called by muse, mutect2, varscan2
- DNAH8 | c.4599G>A p.Q1533= | Silent (SNP) | VAF 19/61 reads (31%) | catalogued as COSV59422594, COSV59424140; called by muse, mutect2, varscan2
- DPY19L2 | c.1788G>T p.V596= | Silent (SNP) | VAF 12/57 reads (21%) | catalogued as COSV61038684; called by muse, mutect2, varscan2
- EEF2 | c.1611C>T p.I537= | Silent (SNP) | VAF 36/120 reads (30%) | catalogued as COSV58578536; called by muse, mutect2, varscan2
- FER1L6 | c.2034C>A p.A678= | Silent (SNP) | VAF 16/121 reads (13%) | catalogued as COSV67548002; called by muse, mutect2, varscan2
- FRMPD2 | c.409C>T p.L137= | Silent (SNP) | VAF 21/84 reads (25%) | catalogued as COSV59715020; called by muse, mutect2, varscan2
- FTCD | c.516G>T p.G172= | Silent (SNP) | VAF 13/78 reads (17%) | catalogued as COSV99384767; called by muse, mutect2, varscan2
- GPAM | c.549G>T p.P183= | Silent (SNP) | VAF 15/76 reads (20%) | catalogued as COSV62080232; called by muse, mutect2, varscan2
- GRM5 | c.2400C>A p.I800= | Silent (SNP) | VAF 25/79 reads (32%) | catalogued as COSV59590082; called by muse, mutect2, varscan2
- HS3ST5 | c.270C>G p.L90= | Silent (SNP) | VAF 16/75 reads (21%) | catalogued as COSV57134217; called by muse, mutect2, varscan2
- KCNMB1 | c.426C>T p.N142= | Silent (SNP) | VAF 9/47 reads (19%) | catalogued as rs374179746; called by muse, mutect2, varscan2
- LILRB3 | c.909C>T p.S303= | Silent (SNP) | VAF 17/55 reads (31%) | catalogued as rs1291699110; called by muse, mutect2, varscan2
- LRRK1 | c.1152A>G p.E384= | Silent (SNP) | VAF 4/52 reads (8%) | catalogued as COSV52601550; called by muse, mutect2
- LZTS2 | c.345A>C p.A115= | Silent (SNP) | VAF 15/92 reads (16%) | catalogued as COSV64650985; called by muse, mutect2, varscan2
- MCL1 | c.315G>T p.A105= | Silent (SNP) | VAF 10/26 reads (38%) | catalogued as COSV57189795; called by muse, mutect2
- MEPE | c.549T>C p.S183= | Silent (SNP) | VAF 22/82 reads (27%) | catalogued as COSV63071788; called by muse, mutect2, varscan2
- MNDA | c.585G>A p.Q195= | Silent (SNP) | VAF 14/51 reads (27%) | catalogued as COSV63739854, COSV63740454; called by muse, mutect2, varscan2
- NALCN | c.4122G>T p.S1374= | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as COSV51917013; called by muse, mutect2, varscan2
- NELL2 | c.2112T>C p.N704= | Silent (SNP) | VAF 4/40 reads (10%) | catalogued as COSV61568789; called by muse, mutect2, varscan2
- NOTCH2 | c.2679C>A p.G893= | Silent (SNP) | VAF 10/81 reads (12%) | catalogued as COSV56681329, COSV99865513; called by muse, mutect2, varscan2
- NPAS3 | c.1843C>A p.R615= (on ENST00000356141 / NM_001164749.2; = p.R583= on NM_022123.3) | Silent (SNP) | VAF 12/61 reads (20%) | catalogued as COSV100639869, COSV60825596; called by muse, mutect2, varscan2
- OR10A4 | c.642G>T p.L214= | Silent (SNP) | VAF 15/74 reads (20%) | catalogued as COSV65841674; called by muse, mutect2, varscan2
- OR2C3 | c.945C>A p.G315= | Silent (SNP) | VAF 21/56 reads (38%) | catalogued as COSV63574363; called by muse, mutect2, varscan2
- OR51B2 | c.465G>T p.L155= | Silent (SNP) | VAF 13/62 reads (21%) | catalogued as rs942601462, COSV100173310; called by muse, mutect2, varscan2
- OR52J3 | c.480C>G p.P160= | Silent (SNP) | VAF 17/79 reads (22%) | catalogued as COSV66746328; called by muse, mutect2, varscan2
- OR52K2 | c.69A>G p.E23= | Silent (SNP) | VAF 40/106 reads (38%) | catalogued as rs770706403, COSV57834556; called by muse, mutect2, varscan2
- OR5B12 | c.162C>T p.H54= | Silent (SNP) | VAF 11/60 reads (18%) | catalogued as COSV56903904; called by muse, mutect2, varscan2
- PASD1 | c.1338C>A p.L446= | Silent (SNP) | VAF 35/136 reads (26%) | catalogued as COSV64854048, COSV64854789; called by muse, mutect2, varscan2
- PCDHB11 | c.1758G>T p.V586= | Silent (SNP) | VAF 26/142 reads (18%) | catalogued as COSV100696933; called by muse, mutect2, varscan2
- PCDHGA9 | c.2079C>G p.L693= | Silent (SNP) | VAF 31/150 reads (21%) | catalogued as COSV53892204, COSV53897420; called by muse, mutect2, varscan2
- RNF150 | c.1038G>T p.L346= | Silent (SNP) | VAF 20/89 reads (22%) | catalogued as COSV60786589; called by muse, mutect2, varscan2
- RNF182 | c.111G>T p.L37= | Silent (SNP) | VAF 38/148 reads (26%) | catalogued as COSV101337854; called by muse, mutect2, varscan2
- S1PR1 | c.105G>A p.L35= | Silent (SNP) | VAF 29/90 reads (32%) | catalogued as rs755893631, COSV59512535; called by muse, mutect2, varscan2
- SH3GL2 | c.669G>A p.L223= | Silent (SNP) | VAF 18/115 reads (16%) | catalogued as rs1049114928, COSV101014105, COSV101014700; called by muse, mutect2, varscan2
- SH3RF2 | c.1539G>T p.R513= | Silent (SNP) | VAF 29/82 reads (35%) | catalogued as COSV63037005; called by muse, mutect2, varscan2
- SIGLEC10 | c.1974C>A p.S658= | Silent (SNP) | VAF 52/180 reads (29%) | catalogued as COSV59478802; called by muse, mutect2, varscan2
- SLC44A1 | c.294C>T p.C98= | Silent (SNP) | VAF 22/79 reads (28%) | catalogued as COSV66024655; called by muse, mutect2, varscan2
- SLC9A6 | c.240G>T p.L80= | Silent (SNP) | VAF 41/224 reads (18%) | catalogued as COSV65787254; called by muse, mutect2, varscan2
- SV2C | c.2148G>C p.L716= | Silent (SNP) | VAF 21/81 reads (26%) | catalogued as COSV59213775; called by muse, mutect2, varscan2
- TRMO | c.231A>T p.L77= | Silent (SNP) | VAF 8/43 reads (19%) | catalogued as COSV63336584; called by muse, mutect2, varscan2
- TTC7B | c.2385G>T p.S795= | Silent (SNP) | VAF 14/39 reads (36%) | catalogued as rs142524402; called by muse, mutect2, varscan2
- VCAM1 | c.963C>T p.P321= | Silent (SNP) | VAF 53/185 reads (29%) | catalogued as COSV54117681; called by muse, mutect2, varscan2
- ZNF318 | c.1725A>T p.P575= | Silent (SNP) | VAF 38/164 reads (23%) | catalogued as COSV58930119; called by muse, mutect2, varscan2
- ZNF560 | c.990T>A p.T330= | Silent (SNP) | VAF 17/70 reads (24%) | catalogued as COSV56865250; called by muse, mutect2, varscan2
- AP000769.5 | chr11:65498992 G>T | 5'Flank (SNP) | VAF 19/95 reads (20%) | called by muse, mutect2, varscan2
- CABP1 | c.655-3765C>A | Intron (SNP) | VAF 5/40 reads (13%) | catalogued as COSV99974570; called by muse, mutect2, varscan2
- CACNA1C | c.1217+312G>A | Intron (SNP) | VAF 4/25 reads (16%) | catalogued as COSV59696281; called by muse, mutect2
- GCNT2 | c.926-34760G>T | Intron (SNP) | VAF 26/100 reads (26%) | catalogued as rs776266980, COSV53942266, COSV99399141; called by muse, mutect2, varscan2
- NPC1 | chr18:23529691 C>T | 3'Flank (SNP) | VAF 15/122 reads (12%) | catalogued as rs373654910; called by muse, mutect2, varscan2
- SNORD114-28 | n.50G>T | RNA (SNP) | VAF 42/123 reads (34%) | called by muse, mutect2, varscan2
- SYNDIG1 | c.-1C>A | 5'UTR (SNP) | VAF 29/110 reads (26%) | catalogued as COSV100965193; called by muse, mutect2, varscan2
- TMEM105 | n.801A>C | RNA (SNP) | VAF 19/136 reads (14%) | catalogued as COSV59654778; called by muse, mutect2, varscan2
- UBTFL2 | n.725G>T | RNA (SNP) | VAF 31/101 reads (31%) | called by muse, mutect2, varscan2
- ZAN | c.7787+28C>A | Intron (SNP) | VAF 11/35 reads (31%) | catalogued as COSV100769396; called by muse, mutect2, varscan2
